Somatic mutation profile of tumor specimen MMRF_2035_1_BM_CD138pos (aliquot MMRF_2035_1_BM_CD138pos_T1_KHS5U_L08083) from MMRF case MMRF_2035, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.8 years (26,948 days).
Specimen MMRF_2035_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48753913-efbb-4e6f-b946-dfa9cbcb2072.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2035_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2035_1_PB_Whole_C2_KHS5U_L08084; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f556615b-bfd8-406b-b0a3-ccd2a3c12b30

The open-access MAF lists 130 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 40, Missense Mutation 36, Silent 20, Intron 17, 5'UTR 5, Splice Site 4, 5'Flank 2, Nonsense Mutation 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRD2 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as rs1314309317; called by muse, mutect2, varscan2
- ADGRL3 | c.746C>G p.T249S (on ENST00000506720 / NM_001322402.2; = p.T181S on NM_015236.6) | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs762481224; called by muse, mutect2, varscan2
- AGPS | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768169404; called by muse, mutect2, varscan2
- ECSIT | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV104374179; called by muse, mutect2
- FLNB | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247642284; called by muse, mutect2, varscan2
- ILVBL | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as rs775641218; called by muse, mutect2, varscan2
- JAGN1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 72/103 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1037552618; called by muse, mutect2, varscan2
- MAT2B | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs994495176; called by muse, mutect2, varscan2
- MYO7A | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1555067582; called by muse, mutect2, varscan2
- PDGFD | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100158110, COSV56389294; called by muse, mutect2, varscan2
- PTPRN | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs763873531, COSV55345622; called by muse, mutect2, varscan2
- TEK | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.533); catalogued as COSV66236510; called by muse, mutect2, varscan2
- TMEM61 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV64874091; called by muse, mutect2, varscan2
- TOR4A | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1341083106; called by muse, mutect2, varscan2
- TRANK1 | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57163235; called by muse, varscan2
- AADAC | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCB1 | c.534T>G p.D178E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ACSF3 | c.822+1G>A p.X274_splice | Splice Site (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- ALKBH3 | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ANKRD23 | c.123A>C p.Q41H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BNIP5 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CCDC141 | c.3600G>A p.M1200I | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- CCDC88C | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CD68 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 115/243 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHL1 | c.2200-1G>A p.X734_splice (on ENST00000397491 / NM_001253387.1; = p.X750_splice on NM_006614.4) | Splice Site (SNP) | VAF 5/18 reads (28%) | called by muse, varscan2
- CHRM3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 187/867 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CHST8 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- CTNND2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DAO | c.656C>G p.P219R | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DCUN1D3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DDX53 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSP90B1 | c.975+2T>G p.X325_splice | Splice Site (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- IGHA1 | c.588_611del p.W196_T203del | In Frame Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, varscan2
- IGKV2-24 | c.51A>C p.G17= | Splice Region (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- ITGA7 | c.1611del p.N538Tfs*12 (on ENST00000555728; = p.N494Tfs*12 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel*, varscan2
- MAPK10 | c.772A>T p.N258Y (on ENST00000359221 / NM_001351625.2; = p.N296Y on NM_002753.5) | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PEX6 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- POF1B | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SUCO | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.21566T>A p.L7189H (on ENST00000591111; = p.L6262H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- VBP1 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZFHX4 | c.3340G>A p.G1114R | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY6 | c.2472C>T p.L824= | Silent (SNP) | VAF 79/183 reads (43%) | called by muse, mutect2, varscan2
- APOLD1 | c.346C>T p.L116= (on ENST00000326765 / NM_001130415.2; = p.L85= on NM_030817.3) | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- BRCC3 | c.279T>G p.S93= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- COL5A1 | c.2601C>T p.L867= | Silent (SNP) | VAF 72/280 reads (26%) | catalogued as rs767014646; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH7 | c.2712G>A p.A904= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs554616778, COSV56768773; called by muse, mutect2, varscan2
- EIF2B5 | c.1707A>G p.L569= (on ENST00000647909; = p.L561= on NM_003907.3) | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as rs756747325; called by muse, mutect2, varscan2
- GALNT17 | c.390G>A p.L130= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100353938; called by muse, mutect2, varscan2
- GLI2 | c.3957C>T p.G1319= (on ENST00000361492 / NM_001374353.1; = p.G1336= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- LRP2 | c.7530A>G p.R2510= | Silent (SNP) | VAF 64/142 reads (45%) | called by muse, mutect2, varscan2
- MAP1A | c.2541G>A p.E847= | Silent (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- OLIG3 | c.96C>T p.H32= | Silent (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- PDE4D | c.1824G>A p.R608= (on ENST00000340635 / NM_001104631.2; = p.R472= on NM_006203.4) | Silent (SNP) | VAF 68/289 reads (24%) | called by muse, varscan2
- PEG3 | c.4452T>C p.G1484= | Silent (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- PLEC | c.5307G>A p.E1769= (on ENST00000322810 / NM_201380.4; = p.E1659= on NM_000445.5) | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- SLC38A10 | c.2748G>A p.G916= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs989738622; called by muse, mutect2
- TANC1 | c.5088A>T p.G1696= | Silent (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- TCTA | c.12C>T p.S4= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- TMCC2 | c.1113G>A p.R371= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs368917544; called by muse, mutect2, varscan2
- TYK2 | c.2655G>A p.P885= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as rs960841634; called by muse, varscan2
- ZNF585B | c.333C>T p.I111= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs761267729, COSV57217149; called by muse, mutect2, varscan2
- AC007040.2 | c.-161G>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs1177331630; called by muse, mutect2, varscan2
- ADH1B | c.*1112A>C | 3'UTR (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- ARFIP2 | chr11:6481392 G>A | 5'Flank (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2
- ARID2 | chr12:45727729 G>A | 5'Flank (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- ARL8B | c.*115C>T | 3'UTR (SNP) | VAF 124/483 reads (26%) | called by muse, mutect2, varscan2
- ASGR1 | c.188-27C>A | Intron (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- BOLA3 | c.*163G>C | 3'UTR (SNP) | VAF 45/118 reads (38%) | catalogued as COSV99768113; called by muse, mutect2, varscan2
- C2CD5 | c.*875A>G | 3'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as rs1289931910; called by muse, mutect2, varscan2
- CHRND | c.*183_*187del | 3'UTR (DEL) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- CRCP | c.*1284T>A | 3'UTR (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- CREBZF | c.*288-333A>C | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- CUX1 | c.*4206G>A | 3'UTR (SNP) | VAF 31/136 reads (23%) | catalogued as rs1006716550; called by muse, mutect2, varscan2
- DLGAP1 | c.*2865C>T | 3'UTR (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- DNAJC25 | c.*1015C>T | 3'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- DOCK1 | c.1561+58C>T | Intron (SNP) | VAF 32/105 reads (30%) | catalogued as rs890055478; called by muse, mutect2, varscan2
- DPY19L1 | c.*631T>A | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- ESRRG | c.*1632T>G | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- EXD1 | c.*303A>C | 3'UTR (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- EXD3 | c.516+126G>A | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- FAU | c.220+143A>T | Intron (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*2559A>C | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2
- FRMD5 | c.*2887A>G | 3'UTR (SNP) | VAF 59/84 reads (70%) | called by muse, mutect2, varscan2
- GABARAPL2 | c.*445C>G | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- GNPAT | c.*65C>G | 3'UTR (SNP) | VAF 129/437 reads (30%) | called by muse, mutect2, varscan2
- GPR19 | c.-8A>C | 5'UTR (SNP) | VAF 106/249 reads (43%) | called by muse, mutect2, varscan2
- HELLPAR | n.201676A>G | RNA (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+476A>T | Intron (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.-27A>C | 5'UTR (SNP) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- IRF4 | c.*1378T>G | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- KCNAB2 | c.805-86G>A | Intron (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- KIF3C | c.*261G>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | catalogued as rs748361593; called by muse, mutect2, varscan2
- LRRC28 | c.168+3191C>G | Intron (SNP) | VAF 74/293 reads (25%) | called by muse, varscan2
- LSM2 | c.-199C>G | 5'UTR (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- MCF2 | c.*311C>T | 3'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as rs1404331818; called by muse, mutect2, varscan2
- MDGA1 | c.*3392C>T | 3'UTR (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- MEF2A | c.*3027A>C | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- NCKAP5L | c.3792+94T>C | Intron (SNP) | VAF 59/137 reads (43%) | called by muse, mutect2, varscan2
- NFIB | c.*5203T>A | 3'UTR (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- NRSN1 | c.*958G>A | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- NUMB | c.*438G>A | 3'UTR (SNP) | VAF 25/46 reads (54%) | catalogued as rs1438958841; called by muse, mutect2, varscan2
- OPRM1 | c.1165-10839C>A | Intron (SNP) | VAF 67/195 reads (34%) | called by muse, mutect2, varscan2
- PBX1 | c.*1741G>T | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- PIK3R2 | c.1809-74C>G | Intron (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- PRRT1B | c.*29G>A | 3'UTR (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- R3HDM2 | c.*819dup | 3'UTR (INS) | VAF 105/259 reads (41%) | catalogued as rs914871814; called by mutect2, varscan2
- RANBP17 | c.*488G>C | 3'UTR (SNP) | VAF 49/137 reads (36%) | called by muse, mutect2, varscan2
- RGS7BP | c.-407C>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs1003327538; called by muse, mutect2
- SLC27A5 | c.1668-20C>T | Intron (SNP) | VAF 60/192 reads (31%) | catalogued as rs901092138; called by muse, mutect2, varscan2
- SLC36A2 | c.*31C>T | 3'UTR (SNP) | VAF 50/215 reads (23%) | catalogued as rs749281540, COSV58862866; called by muse, mutect2, varscan2
- SSR2 | c.363+63G>A | Intron (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.503+633A>G | Intron (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- STK17B | c.*3746C>T | 3'UTR (SNP) | VAF 58/148 reads (39%) | catalogued as rs1447281657, COSV55830012; called by muse, mutect2, varscan2
- TAFA5 | c.*1769A>C | 3'UTR (SNP) | VAF 39/88 reads (44%) | catalogued as COSV60979100; called by muse, mutect2, varscan2
- TBCE | c.644+83C>T | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2
- TBXAS1 | c.333+2369C>T | Intron (SNP) | VAF 85/240 reads (35%) | catalogued as COSV54939777; called by muse, mutect2, varscan2
- TCTEX1D1 | c.*334A>G | 3'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- TLX3 | c.*132C>T | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- TMTC1 | c.*5790A>G | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- TULP4 | c.*4948G>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | catalogued as rs964121460; called by muse, mutect2, varscan2
- TWF1 | c.*119T>C | 3'UTR (SNP) | VAF 60/139 reads (43%) | called by muse, mutect2, varscan2
- UBXN10 | c.*2111G>A | 3'UTR (SNP) | VAF 35/125 reads (28%) | called by muse, mutect2, varscan2
- UNC80 | c.*486T>C | 3'UTR (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- WDR17 | chr4:176180826 A>G | 3'Flank (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- ZBBX | c.*258_*259del | 3'UTR (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- ZNF726 | c.226+789G>A | Intron (SNP) | VAF 19/62 reads (31%) | catalogued as rs930860375; called by muse, mutect2, varscan2
- ZNF775 | c.*401del | 3'UTR (DEL) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
